TCGA case TCGA-CC-5261 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ad7f17e-b3b8-40e9-aab8-5a17e0aec408

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Dead; Days to death: 97 days.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 44.8 years (16,373 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 12 days; Disease response: Tumor Free.
- Days to follow up: 97 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / Hepatitis C Antibody.
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 175 cm; BMI: 18.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CC-5261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 450 mg.
  Slide TCGA-CC-5261-01A-01-BS1: Section location: Bottom; Percent tumor cells: 77; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 20.
- Sample TCGA-CC-5261-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CC-5261-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Surgical procedure other: Hepatic Resection.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 97 days; disease-specific survival: no event (censored), 97 days; progression-free interval: no event (censored), 97 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CC-5261-01A-01D-A12Y-01): tumor purity 0.49, ploidy 3.19, whole-genome doublings 1.
